CPTAC case C3L-03467 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a248db42-2ca8-47fb-a4dd-9622ae192b21

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1944; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 73.3 years (26,781 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIC1; FIGO stage: Stage IIIC1; Tumor grade: G3; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,853 days (5.1 years); Progression or recurrence: no; Days to last follow up: 1,853 days (5.1 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.2 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 12; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 410 days (1.1 years); Disease response: Complete Response; ECOG performance status: 1.
- Days to follow up: 411 days (1.1 years); Disease response: Tumor Free.
- Days to follow up: 725 days (2.0 years); Disease response: Tumor Free.
- Days to follow up: 1,123 days (3.1 years); Disease response: Tumor Free.
- Days to follow up: 1,488 days (4.1 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,853 days (5.1 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 83.46 kg; Height: 160.02 cm; BMI: 32.59; Hormonal contraceptive use: Former User.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-03467-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 27 days; Initial weight: 309 mg; Time between clamping and freezing: 9 minutes; Time between excision and freezing: 2 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03467-21: Section location: Endometrium; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-03467-11: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 27 days; Time between clamping and freezing: 9 minutes; Time between excision and freezing: 2 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-03467-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 27 days; Method of sample procurement: Blood Draw.
